Somatic mutation profile of tumor specimen TARGET-20-PATBRA-03A (aliquot TARGET-20-PATBRA-03A-01D) from TARGET case TARGET-20-PATBRA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,376 days).
Specimen TARGET-20-PATBRA-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30c82897-da2e-4185-ae57-eee440cb723a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATBRA-14A (Bone Marrow Normal), aliquot TARGET-20-PATBRA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26a88afe-ae5f-40d2-a7ed-e8d7049ab250

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA6 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs773107512, COSV67559447, COSV67572371; called by muse, mutect2
